Gene-level copy-number profile of tumor specimen TCGA-B6-A400-01A from TCGA case TCGA-B6-A400, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 43.9 years (16,022 days).
Specimen TCGA-B6-A400-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.42d878a6-160a-40a3-a72b-f5e9a4270b2d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A400-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b49637d2-c4aa-4a0a-af17-ec4e9754713a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,312; copy number 2: 21,738; copy number 3: 17,605; copy number 4: 8,656; copy number 5: 3,290; copy number 6: 2,240; copy number 7: 802; copy number 8: 115; copy number 9: 59.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A400-01A-11D-A238-01): tumor purity 0.55, ploidy 2.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,918 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,228,319–3,068,437, 30 genes, copy number 5 (within-gene range 2–5): SKI, AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10, PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, AL589702.1, ACTRT2, PRDM16-DT.
- chr1:104,998,406–105,032,365, 1 gene, copy number 5: AL591888.1.
- chr1:110,150,494–111,185,104, 35 genes, copy number 5 (within-gene range 2–5): SLC6A17, SLC6A17-AS1, AL355990.1, LINC02586, KCNC4, AL137790.2, AL137790.1, RBM15-AS1, RBM15, LAMTOR5-AS1, SLC16A4, AL355488.1, LAMTOR5, PROK1, AL358215.1, AL358215.2, AL358215.3, CYMP, CYMP-AS1, KCNA10, KCNA2, AL365361.1, KCNA3, Y_RNA, NRBF2P3, OR11I1P, CD53, AL360270.2, AL360270.1, LRIF1, AL360270.3, CCNT2P1, RNA5SP54, DRAM2, CEPT1.
- chr1:119,558,755–164,357,364, 945 genes, copy number 5–7 (broad region; genes not listed).
- chr2:48,809,340–49,419,013, 1 gene, copy number 5 (within-gene range 4–5): AC009975.1.
- chr2:48,962,157–64,019,428, 204 genes, copy number 5 (broad region; genes not listed).
- chr3:144,186,905–198,222,513, 935 genes, copy number 5–6 (broad region; genes not listed).
- chr5:16,615,926–21,779,522, 80 genes, copy number 5 (broad region; genes not listed).
- chr5:21,882,585–21,884,310, 1 gene, copy number 5: HSPD1P1.
- chr6:167,607–14,231,570, 267 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:60,719,222–65,707,226, 36 genes, copy number 5 (within-gene range 4–5): GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1.
- chr8:34,174,886–138,497,261, 1,518 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:141,389,939–145,066,685, 180 genes, copy number 5 (broad region; genes not listed).
- chr10:58,869,184–59,363,181, 7 genes, copy number 5 (within-gene range 2–5): RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1.
- chr11:54,635,037–58,904,215, 219 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:38,078,529–43,806,328, 84 genes, copy number 5 (broad region; genes not listed).
- chr13:100,708,325–101,059,286, 1 gene, copy number 6 (within-gene range 4–6): NALCN-AS1.
- chr13:100,934,023–114,337,626, 198 genes, copy number 6–8 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 3–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr18:47,390–11,149,569, 228 genes, copy number 7–9 (broad region; genes not listed).
- chr19:29,205,320–45,076,587, 690 genes, copy number 5–8 (broad region; genes not listed).
- chr20:8,077,251–8,968,360, 1 gene, copy number 6 (within-gene range 3–6): PLCB1.
- chr20:8,248,704–8,256,918, 1 gene, copy number 6: PLCB1-IT1.
- chr20:9,505,180–13,996,443, 62 genes, copy number 5–6 (broad region; genes not listed).
- chr20:14,003,508–14,003,699, 1 gene, copy number 5: RPS3P1.
- chr21:32,020,966–39,529,855, 189 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,564. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
